CCDI case PBBYZH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/20268e79-c61f-4a65-93ef-ab0e56654bec

Demographics
Sex at birth: female.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 9.0 years (3,271 days).

Biospecimens (3 samples)
- Sample 0DLA0Z: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLA1Y: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DLA2T: Tissue type: Tumor; Specimen type: Solid Tissue.
